Somatic mutation profile of tumor specimen MP2PRT-PASRRX-TMP1-A (aliquot MP2PRT-PASRRX-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASRRX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.6 years (1,665 days).
Specimen MP2PRT-PASRRX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62f16d71-daed-467f-babf-acf6f22647ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRRX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRRX-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea1df625-0f5a-4b01-99f0-d7eacb45187b

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 97/271 reads (36%) | catalogued as rs899345535; called by muse, mutect2, varscan2
- ATRX | c.6848A>T p.K2283M | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRPM7 | c.3604G>C p.E1202Q | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.224); called by muse, mutect2
- CLEC16A | c.2949C>T p.L983= | Silent (SNP) | VAF 235/537 reads (44%) | catalogued as rs201719789, COSV55489656; called by muse, mutect2, varscan2
